Somatic mutation profile of tumor specimen MMRF_2831_1_BM_CD138pos (aliquot MMRF_2831_1_BM_CD138pos_T1_KHS5U_L16548) from MMRF case MMRF_2831, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.7 years (23,984 days).
Specimen MMRF_2831_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d7ea9b4-1093-45cd-afd2-a2d317d0bd84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2831_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2831_1_PB_WBC_C2_KHS5U_L16595; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e109587-1c69-4efc-a034-42d954722f84

The open-access MAF lists 68 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 19, Intron 10, Silent 8, RNA 2, 5'UTR 1, Frame Shift Del 1, Splice Region 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA1D | c.1598G>A p.C533Y | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as rs748375709; called by muse, mutect2
- ARHGAP33 | c.2332G>T p.V778L | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as rs150394522; called by muse, mutect2, varscan2
- CXorf66 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.246); catalogued as COSV100983927; called by muse, mutect2, varscan2
- DNM2 | c.1810G>A p.E604K (on ENST00000355667 / NM_001005360.3; = p.E600K on NM_004945.3) | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs951875086, COSV58956683, COSV58958283; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPX | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1021218566; called by muse, mutect2, varscan2
- H1-4 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV56799673; called by muse, mutect2, varscan2
- IGHV2-70 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs557763852; called by muse, varscan2
- IGHV3-33 | c.296A>C p.Y99S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.071); catalogued as rs376878952; called by muse, varscan2
- IGLV3-1 | c.47-2A>G p.X16_splice | Splice Site (SNP) | VAF 38/161 reads (24%) | catalogued as rs181922188; called by muse, varscan2
- ITGA8 | c.398A>G p.N133S | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs769840281; called by muse, mutect2
- KCNV1 | c.223T>C p.Y75H | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs751534416; called by muse, mutect2, varscan2
- LOXL4 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs369867446, COSV53259893; called by muse, mutect2, varscan2
- NRM | c.134-3T>C | Splice Region (SNP) | VAF 5/15 reads (33%) | catalogued as rs1311821421; called by muse, mutect2, varscan2
- PCSK6 | c.2566G>A p.V856M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs778468256; called by muse, varscan2
- RUBCNL | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as rs759820353; called by muse, mutect2, varscan2
- SPTBN5 | c.5075T>C p.L1692P | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1157360482; called by mutect2, varscan2
- CACNA1B | c.1811A>G p.N604S | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CAPN14 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.185); called by muse, mutect2
- DIRAS3 | c.273C>A p.D91E | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DND1 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- EIF2AK3 | c.125A>G p.E42G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GSAP | c.2299T>A p.W767R | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PUM3 | c.1333T>G p.L445V | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RSKR | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 44/259 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- USP53 | c.2594_2624del p.S865* | Frame Shift Del (DEL) | VAF 13/163 reads (8%) | called by mutect2, pindel
- VN1R2 | c.859G>T p.V287F | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- WDR33 | c.1331T>C p.M444T | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- HSPG2 | c.915C>T p.D305= | Silent (SNP) | VAF 42/154 reads (27%) | catalogued as rs554413823, COSV65930402; called by muse, mutect2, varscan2
- IGHD2-21 | c.6A>C p.I2= | Silent (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- KLF15 | c.780C>T p.F260= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as rs755498436, COSV99955012; called by muse, mutect2, varscan2
- LHFPL2 | c.507T>C p.H169= | Silent (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- NID1 | c.2121C>T p.T707= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- NRG1 | c.984A>C p.A328= (on ENST00000405005 / NM_013964.5; = p.A333= on NM_013956.5) | Silent (SNP) | VAF 30/154 reads (19%) | called by muse, mutect2, varscan2
- TECPR2 | c.162C>T p.I54= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as rs761145715; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1605A>G p.Q535= | Silent (SNP) | VAF 48/208 reads (23%) | catalogued as rs750063211, COSV100362865; called by muse, mutect2, varscan2
- ABHD13 | c.*189A>G | 3'UTR (SNP) | VAF 4/50 reads (8%) | catalogued as rs1460963669; called by muse, mutect2
- AC103993.1 | n.1029C>A | RNA (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- AHI1 | c.3109+6961A>C | Intron (SNP) | VAF 16/121 reads (13%) | catalogued as COSV99663468; called by muse, mutect2, varscan2
- AP001122.1 | n.281G>A | RNA (SNP) | VAF 40/220 reads (18%) | called by muse, mutect2, varscan2
- BCL11A | c.385+4056A>G | Intron (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- CHN1 | c.-105G>A | 5'UTR (SNP) | VAF 14/52 reads (27%) | called by muse, varscan2
- CLINT1 | c.1380+1088A>G | Intron (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- CRISP2 | c.*398C>G | 3'UTR (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- CSNK2B | c.*67C>G | 3'UTR (SNP) | VAF 22/468 reads (5%) | called by muse, mutect2
- DNM1L | c.*2105T>C | 3'UTR (SNP) | VAF 9/49 reads (18%) | catalogued as rs1353608318; called by muse, mutect2, varscan2
- FBXO21 | c.*88G>A | 3'UTR (SNP) | VAF 8/40 reads (20%) | catalogued as rs779465939; called by muse, mutect2, varscan2
- FER | c.*6065A>G | 3'UTR (SNP) | VAF 5/27 reads (19%) | catalogued as rs1213334523; called by muse, mutect2, varscan2
- ISCA1 | c.242-1225A>T | Intron (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- KPNA5 | c.*45+510G>T | Intron (SNP) | VAF 10/39 reads (26%) | called by mutect2, varscan2
- LITAF | c.*33G>A | 3'UTR (SNP) | VAF 20/105 reads (19%) | catalogued as rs766852963; called by muse, mutect2, varscan2
- LTB | c.163-38G>C | Intron (SNP) | VAF 63/302 reads (21%) | called by muse, mutect2, varscan2
- MLLT3 | c.*515A>C | 3'UTR (SNP) | VAF 36/90 reads (40%) | called by muse, mutect2, varscan2
- NAV2 | c.2977-20C>G | Intron (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- NKAPD1 | c.*227_*228del | 3'UTR (DEL) | VAF 4/42 reads (10%) | catalogued as rs1491340302; called by pindel, varscan2
- NPTXR | c.*786C>A | 3'UTR (SNP) | VAF 43/140 reads (31%) | called by muse, mutect2, varscan2
- PPIL2 | c.*2733G>A | 3'UTR (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- PRKG1 | c.*432T>C | 3'UTR (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- RBM48 | c.1017+510C>G | Intron (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- SF3A2 | c.245+76A>G | Intron (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- SLC52A2 | c.-110-117T>C | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- SPTLC2 | c.*4575A>C | 3'UTR (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975590 C>T | 5'Flank (SNP) | VAF 53/123 reads (43%) | catalogued as rs939978850, COSV66081290, COSV66081942; called by muse, mutect2, varscan2
- USP31 | c.*2956C>T | 3'UTR (SNP) | VAF 15/63 reads (24%) | catalogued as rs894246040; called by muse, mutect2, varscan2
- VPS29 | c.*234C>T | 3'UTR (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- XPO4 | c.*2690T>A | 3'UTR (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- ZNF25 | c.*1537A>T | 3'UTR (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- ZNF703 | c.*797C>A | 3'UTR (SNP) | VAF 66/274 reads (24%) | catalogued as rs1161540457; called by muse, mutect2, varscan2
- ZZZ3 | c.*1201C>G | 3'UTR (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
